Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7097, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7097-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (B) COMPLETE RESECTION ANTERIOR MANDIBLE:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA INVADING BONE.
Bone margins of resection free of tumor.

Entire report and diagnosis completed by: [REDACTED]

DIAGNOSIS

- (A) CONTENTS, LEVEL I AND SUBMENTAL DISSECTION:
Submandibular gland with fibrous inflammation of tumor.
Five lymph nodes, no tumor.
- (B) COMPLETE RESECTION ANTERIOR MANDIBLE AND FLOOR OF MOUTH:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA WITH LYMPHATIC AND
PERINEURAL INVASION FLOOR OF MOUTH. TUMOR CLOSE TO MARGIN OF
RESECTION.
Bone submitted for decalcification, supplemental report will follow.

Entire report and diagnosis completed by: [REDACTED]

GROSS DESCRIPTION

(A) CONTENTS, LEVEL I AND SUBMENTAL DISSECTION - A 10.0 x 3.5 x 2.5 cm portion of yellow-tan adipose tissue. Within the adipose tissue is a 4.0 x 2.0 x 1.8 cm lobulated salivary gland. The salivary gland parenchyma is grossly unremarkable. The adipose tissue contains multiple lymph nodes which measure up to 1.0 cm in greatest dimension. No matted or necrotic lymph nodes are present. A representative sample of the specimen including all lymph node tissue is submitted as follows: A1-A2, salivary gland; A3, one lymph node bisected; A4, one lymph node bisected; A5, five possible lymph nodes.

(B) COMPOSITE RESECTION ANTERIOR MANDIBLE ON FLOOR OF MOUTH - A anterior mandible with skeletal muscle, floor of mouth, and inferior soft tissue (overall measurement 2.5 x 4.0 x 4.0 cm) with the anterior skin ellipse (2.7 x

Page 1 of 2

[page 2 of 2]
Case type: Surgical History

0.9 cm) and anterior soft tissue (5.0 x 3.2 x 2.0 cm).

An irregular, tan-pink, exophytic area involves the floor of the mouth which expands into the anterior soft tissue (4.0 x 3.5 x 3.0 cm). A rim of white-pink mucosa is taken around the exophytic mucosal lesion. The closest mucosal margin and right posterior margin is 0.5 cm. The anterior mucosal margin has been disrupted but is free of tumor. The anterior soft tissue margin has focally separated from the mandible but the soft tissue margins are free of tumor. The mandibular bony margins are unremarkable.

INK CODE: Blue-margin.

SECTION CODE: B1-B19, posterior mucosa soft tissue submitted from right to left and anterior skin and soft tissue submitted entirely from right to left according to Dr. [REDACTED]. The mandible has been sent to the bone lab for decalcification.

SNOMED CODES

M-80703 T-51004

Source: NCI Genomic Data Commons file 84773ec3-6b23-443b-9dae-29e8f0303b4a (TCGA-CV-7097.74CD30C9-5447-4953-A029-30CBBC40F61E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).